Somatic mutation profile of tumor specimen 0DIKK3 from CCDI case PBBVKE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 12.8 years (4,690 days).
Specimen 0DIKK3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) add63951-33dd-411c-a615-ca52bdd78490.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIKJG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14cf5c36-c5c0-45e9-b132-f6c3d77d5325

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 1, Intron 1, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 34/1023 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- SYCP2L | c.689A>T p.Q230L | Missense Mutation (SNP) | VAF 146/709 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF682 | c.684A>C p.P228= | Silent (SNP) | VAF 9/202 reads (4%) | catalogued as rs1215931064, COSV62066272; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/130 reads (9%) | called by muse, varscan2
- CALM3 | chr19:46600931 A>G | 5'Flank (SNP) | VAF 149/768 reads (19%) | called by muse, mutect2, varscan2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 20/540 reads (4%) | catalogued as rs926414386, COSV100695372; called by muse, mutect2
